Somatic mutation profile of tumor specimen TCGA-44-4112-01B (aliquot TCGA-44-4112-01B-06D-A271-08) from TCGA case TCGA-44-4112, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-44-4112-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c33aa13a-61cc-432d-9881-b43e150ee9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-4112-10A (Blood Derived Normal), aliquot TCGA-44-4112-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/969aad40-d48a-4ab9-979b-3e6ca0127d12

The open-access MAF lists 364 somatic variants for this specimen: 283 protein-altering or splice-affecting, 73 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 73, Nonsense Mutation 20, Frame Shift Del 11, Splice Site 9, Splice Region 3, Frame Shift Ins 3, RNA 3, Intron 2, Nonstop Mutation 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.6688-1G>T p.X2230_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | catalogued as rs1057520697, COSV54202103, COSV54217068; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV52217797; called by muse, mutect2, varscan2
- ABCA13 | c.7558G>T p.D2520Y | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV71282907, COSV71294006; called by muse, mutect2, varscan2
- ACSL5 | c.570G>T p.K190N (on ENST00000354273; = p.K246N on NM_016234.3) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287081923, COSV61128656; called by muse, mutect2
- ACTN2 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63971584, COSV63972780; called by muse, mutect2, varscan2
- ADAD1 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56641180; called by muse, mutect2, varscan2
- ADGRA3 | c.3116G>T p.S1039I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV51560144; called by muse, mutect2, varscan2
- ADGRG7 | c.80T>A p.L27Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56293359; called by muse, mutect2, varscan2
- AGAP6 | c.706G>T p.G236W (on ENST00000374056 / NM_001365867.1; = p.G259W on NM_001077665.2) | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65017264; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by mutect2, varscan2
- AK5 | c.1385G>T p.G462V (on ENST00000354567 / NM_174858.3; = p.G436V on NM_012093.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60967087, COSV60971382; called by muse, mutect2, varscan2
- AKAP1 | c.2432G>C p.R811T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61804980; called by muse, mutect2, varscan2
- ALDH1B1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890973; called by muse, mutect2, varscan2
- ALDH1B1 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100890974; called by muse, mutect2, varscan2
- ALK | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV66556053; called by muse, mutect2, varscan2
- AMACR | c.914A>T p.H305L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1234892826, COSV56869419; called by muse, mutect2, varscan2
- ANK1 | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1363933552, COSV55871780; called by muse, mutect2, varscan2
- ANK1 | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV55871816; called by muse, mutect2, varscan2
- ANK2 | c.400T>A p.L134I | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52144225; called by muse, mutect2
- ANK2 | c.4545C>G p.I1515M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as COSV52144247; called by muse, mutect2, varscan2
- AOX1 | c.3673C>A p.Q1225K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV53495023; called by muse, mutect2, varscan2
- AQP9 | c.239-1G>T p.X80_splice | Splice Site (SNP) | VAF 31/166 reads (19%) | catalogued as COSV54967309; called by muse, mutect2, varscan2
- ARHGAP32 | c.3925C>T p.P1309S (on ENST00000310343 / NM_001378025.1; = p.P960S on NM_014715.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV59842819; called by muse, mutect2, varscan2
- AS3MT | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100185808, COSV54915471; called by muse, mutect2, varscan2
- ASPM | c.4072T>G p.W1358G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257499021, COSV54124019; called by mutect2, varscan2
- ATP1A2 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483366741, COSV63402010, COSV63403080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C20orf194 | c.3421+1G>T p.X1141_splice | Splice Site (SNP) | VAF 6/79 reads (8%) | catalogued as COSV52690812; called by muse, mutect2
- C2CD6 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV53790790; called by muse, mutect2, varscan2
- CA10 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.2); catalogued as COSV53336161; called by muse, mutect2, varscan2
- CA10 | c.494T>A p.L165Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53336178; called by muse, mutect2, varscan2
- CACNA1E | c.1339A>T p.I447F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV62381249; called by muse, varscan2
- CACNA1E | c.3616A>T p.I1206L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV62381263; called by muse, mutect2, varscan2
- CACNA1H | c.4660G>T p.V1554L | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV61982951; called by muse, mutect2, varscan2
- CACNA2D3 | c.1782G>T p.G594= | Splice Region (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55510827; called by muse, mutect2, varscan2
- CAPN11 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1169872168, COSV67235973; called by muse, mutect2, varscan2
- CAPRIN2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs755333884, COSV51830095, COSV51833932; called by muse, mutect2, varscan2
- CASR | c.1869C>A p.N623K (on ENST00000490131; = p.N700K on NM_000388.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV56133948, COSV56136537; called by muse, mutect2, varscan2
- CCDC185 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV64820196; called by muse, mutect2, varscan2
- CCDC8 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV56772110; called by muse, mutect2, varscan2
- CCT6B | c.1102A>T p.N368Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58487678; called by muse, mutect2, varscan2
- CD163 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV63129105; called by muse, mutect2, varscan2
- CDH6 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54063505; called by muse, mutect2, varscan2
- CDH7 | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59881102; called by muse, mutect2
- CEMIP2 | c.4042G>T p.V1348L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV65485416; called by muse, mutect2, varscan2
- CFAP161 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54428277; called by muse, mutect2, varscan2
- CMAS | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 7/57 reads (12%) | catalogued as COSV57555910; called by muse, mutect2, varscan2
- CMTR2 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV57602427; called by muse, mutect2, varscan2
- COL11A1 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62171809; called by muse, mutect2, varscan2
- COL14A1 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV52846519; called by muse, mutect2, varscan2
- COL3A1 | c.4021G>T p.G1341C | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140646380, COSV58581376; called by muse, mutect2, varscan2
- COL4A2 | c.2426-2A>G p.X809_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV64624414; called by muse, mutect2, varscan2
- CPPED1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55495415, COSV55498088, COSV55498520; called by muse, mutect2, varscan2
- CPXCR1 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV52160884; called by muse, mutect2, varscan2
- CRB1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369775002, COSV66328542; called by muse, mutect2
- CSMD1 | c.1293G>T p.Q431H (on ENST00000520002; = p.Q430H on NM_033225.6) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV68164438; called by mutect2, varscan2
- CTNNB1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV62688598; called by muse, mutect2, varscan2
- CTPS1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.665); catalogued as COSV65451680; called by muse, mutect2, varscan2
- CUX1 | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52890038, COSV99469960; called by muse, mutect2, varscan2
- DLGAP2 | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70093565, COSV70097468; called by muse, mutect2, varscan2
- DOP1B | c.6628C>G p.L2210V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV67690556; called by mutect2, varscan2
- DPP6 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.289); catalogued as COSV68052000; called by muse, varscan2
- EEF2K | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53778235; called by muse, mutect2, varscan2
- ELSPBP1 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60412718; called by muse, mutect2
- EML2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99840282; called by muse, mutect2, varscan2
- EPC1 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53922877; called by muse, mutect2, varscan2
- EPCAM | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.737); catalogued as rs770114313, COSV55392189; called by muse, mutect2, varscan2
- EPHX1 | c.67A>C p.K23Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV55298454; called by muse, mutect2, varscan2
- ERLEC1 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1163332248, COSV51750457; called by muse, mutect2, varscan2
- ESPNL | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs749808035, COSV58031919; called by muse, mutect2, varscan2
- F5 | c.1514A>T p.Y505F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63120088; called by muse, mutect2, varscan2
- FAT1 | c.8788G>T p.D2930Y | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71671704; called by muse, mutect2, varscan2
- FAT4 | c.6986G>C p.R2329P | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV58670368; called by muse, mutect2, varscan2
- FBXO16 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100672014, COSV60774370; called by muse, mutect2, varscan2
- FCRL5 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.072); catalogued as COSV62511063; called by muse, mutect2, varscan2
- FER | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as COSV55282013; called by muse, mutect2, varscan2
- FEV | c.290A>T p.N97I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55386167; called by muse, mutect2, varscan2
- FILIP1L | c.2792C>G p.T931R (on ENST00000354552 / NM_182909.3; = p.T691R on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202241125, COSV58764433; called by muse, mutect2, varscan2
- FPR2 | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV60671776, COSV60674112; called by muse, mutect2
- FRAS1 | c.8471A>G p.H2824R | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as COSV53586785; called by muse, mutect2, varscan2
- FREM1 | c.2861T>A p.V954D | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66517146; called by muse, mutect2, varscan2
- FRMD7 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.52); catalogued as COSV53744471; called by muse, mutect2, varscan2
- FSCB | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV61216383; called by muse, mutect2, varscan2
- FUT1 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59567282, COSV59568535; called by muse, mutect2, varscan2
- GALR1 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100232022; called by muse, mutect2, varscan2
- GALR1 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100231890, COSV100232024; called by muse, mutect2, varscan2
- GPAT3 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV52355087; called by muse, mutect2, varscan2
- GPATCH1 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV50111065; called by muse, mutect2, varscan2
- GPM6A | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.376); catalogued as COSV54531166; called by muse, mutect2, varscan2
- GRK5 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64865462; called by muse, mutect2, varscan2
- GRM1 | c.2569C>A p.R857S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51108030; called by muse, mutect2, varscan2
- GRSF1 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54654393, COSV54656122; called by muse, mutect2, varscan2
- GUCY1A1 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.173); catalogued as COSV56648763; called by muse, mutect2, varscan2
- HDAC5 | c.1322A>T p.H441L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV56817011; called by muse, mutect2, varscan2
- HECW1 | c.761A>T p.K254M | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV67820928, COSV67826745; called by muse, mutect2, varscan2
- HGF | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.052); catalogued as COSV55944972; called by muse, mutect2, varscan2
- HIPK2 | c.2375G>T p.R792L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV61225310; called by muse, mutect2, varscan2
- HNF4A | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1413804456, COSV57379142; called by muse, mutect2, varscan2
- HPCAL4 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65716021; called by muse, mutect2, varscan2
- HR | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs185501052, COSV57190474; called by muse, mutect2, varscan2
- HTR5A | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55280216; called by muse, mutect2, varscan2
- ICE1 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV56818529; called by muse, mutect2
- IL4R | c.1361A>T p.K454M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV50138118; called by muse, mutect2, varscan2
- INSC | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV65408583; called by muse, mutect2, varscan2
- IRAK3 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV54159106; called by muse, mutect2
- ITGBL1 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101084534, COSV65934807; called by muse, mutect2, varscan2
- IVL | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs1271584586, COSV64215377, COSV64217243; called by muse, mutect2, varscan2
- JADE2 | c.1438A>G p.R480G | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50911504; called by muse, mutect2, varscan2
- JCAD | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 11/146 reads (8%) | catalogued as COSV64757763; called by muse, mutect2
- KCNA1 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.226); catalogued as COSV66836423, COSV66837186; called by muse, mutect2
- KCNA4 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.04); catalogued as rs769344328, COSV60250408; called by muse, mutect2, varscan2
- KCNA4 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60250423; called by muse, mutect2, varscan2
- KCNU1 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67752745; called by muse, mutect2, varscan2
- KCNU1 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV67752751; called by muse, mutect2, varscan2
- KDM5B | c.4273G>C p.E1425Q | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV52503653; called by muse, mutect2, varscan2
- KIF21A | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 23/197 reads (12%) | catalogued as COSV62766681; called by muse, mutect2, varscan2
- KMT2D | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886049484, COSV56416503; ClinVar: uncertain significance; called by muse, varscan2
- KRT3 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV58814429; called by muse, mutect2, varscan2
- KRT75 | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs943299335, COSV52870832; called by muse, mutect2, varscan2
- KRTCAP3 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV51992955; called by muse, mutect2, varscan2
- L1TD1 | c.1164T>A p.D388E | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535166958, COSV63133035; called by muse, mutect2, varscan2
- LAMA1 | c.3046T>A p.C1016S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67531457; called by muse, mutect2, varscan2
- LONP2 | c.995T>A p.I332N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53520167; called by muse, mutect2
- LONP2 | c.997A>T p.R333W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV53520183; called by muse, mutect2
- LRFN3 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.065); catalogued as rs1177593086, COSV55816811; called by muse, mutect2, varscan2
- LRP1B | c.3451C>A p.L1151M | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67183201; called by muse, mutect2, varscan2
- LRRC32 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52631315; called by muse, mutect2, varscan2
- LRRC4 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1470797815, COSV50813162; called by muse, mutect2, varscan2
- LRRC49 | c.1594G>C p.V532L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53007549, COSV53010607; called by muse, mutect2, varscan2
- LRRTM3 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV63660432, COSV63671905; called by muse, mutect2, varscan2
- LSP1 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV61132049; called by muse, mutect2, varscan2
- MAF1 | c.83G>T p.R28M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59362541; called by muse, mutect2, varscan2
- MAGEA10 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV54882635; called by muse, mutect2, varscan2
- MAT1A | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV64744529; called by muse, mutect2, varscan2
- MBTPS1 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.26); catalogued as COSV58569172; called by muse, mutect2, varscan2
- MIDN | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV56293871; called by muse, mutect2
- MIS18BP1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV60368875; called by muse, mutect2
- MKS1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs774076532, COSV58302494; called by muse, mutect2, varscan2
- MMP3 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV55404934, COSV55407467; called by mutect2, varscan2
- MPPED2 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs763721239, COSV63895845; called by mutect2, varscan2
- MPPED2 | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63895850; called by muse, mutect2, varscan2
- MSRB2 | c.511A>C p.N171H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64737083; called by muse, mutect2, varscan2
- MUC16 | c.21541A>T p.T7181S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV67442314; called by muse, mutect2
- MUC17 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 145/749 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761787989, COSV60279249; called by muse, mutect2, varscan2
- MYH1 | c.5599A>T p.R1867W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56843202, COSV99875372; called by muse, mutect2, varscan2
- NALCN | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV51915483; called by muse, mutect2, varscan2
- NELL1 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV54236125, COSV54257333; called by muse, mutect2, varscan2
- NLRP3 | c.2738C>A p.T913K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV60219292, COSV60225201; called by muse, mutect2, varscan2
- NOS1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV57606145; called by muse, mutect2
- NPAP1 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.641); catalogued as COSV61504018, COSV61512136; called by muse, varscan2
- NPFFR2 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100440385, COSV58145977, COSV58149773; called by muse, mutect2, varscan2
- NPSR1 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as COSV62195957; called by muse, mutect2
- NRXN3 | c.1990_1991insA p.R664Qfs*26 (on ENST00000335750 / NM_001330195.2; = p.R291Qfs*26 on NM_004796.6) | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | catalogued as COSV100206783; called by mutect2, pindel, varscan2
- NSG2 | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV57456585; called by muse, mutect2, varscan2
- NSG2 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57456594; called by muse, mutect2, varscan2
- NTRK3 | c.1955G>T p.G652V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV62294707, COSV62313063; called by muse, mutect2, varscan2
- NUDT16 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.316); catalogued as rs1378522401, COSV63248103; called by muse, mutect2, varscan2
- NUTM1 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV60995007; called by muse, mutect2, varscan2
- OR10W1 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- OR2B11 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59509177; called by muse, mutect2, varscan2
- OR4C46 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV60218219; called by muse, mutect2
- OR51F2 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438108, COSV59063609; called by muse, mutect2, varscan2
- OR5F1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53545078; called by muse, mutect2
- OR5M10 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV73242231; called by muse, varscan2
- OR5M8 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59115630; called by muse, mutect2, varscan2
- OR6C74 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV59605663; called by muse, mutect2, varscan2
- OR6X1 | c.896T>C p.L299S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV60009268; called by muse, mutect2, varscan2
- OR9Q1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59035989; called by muse, mutect2, varscan2
- OXT | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV54131670; called by muse, varscan2
- PANK2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV57252803, COSV57255074, COSV57255472; called by muse, mutect2
- PAPPA2 | c.2237A>T p.K746I | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62772303; called by muse, mutect2
- PAPPA2 | c.4238G>T p.G1413V | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV62790056; called by muse, mutect2, varscan2
- PCCA | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66187650; called by muse, mutect2, varscan2
- PCDHA3 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV63538645; called by muse, mutect2
- PCDHB8 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50753597; called by muse, mutect2, varscan2
- PCDHGB7 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV53894124, COSV53920192; called by muse, mutect2, varscan2
- PCF11 | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV53527045; called by muse, mutect2, varscan2
- PDE1C | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV68803371, COSV68812355; called by muse, mutect2
- PDGFRA | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV57264359; called by muse, mutect2, varscan2
- PDS5A | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV57822040; called by muse, mutect2, varscan2
- PIK3C2G | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV56795719; called by muse, mutect2
- PIWIL2 | c.2360G>C p.S787T | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV63249511, COSV63252170; called by muse, mutect2
- PLCB1 | c.3650G>C p.*1217Sext*38 | Nonstop Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV62036601, COSV62040931; called by muse, mutect2
- PLK4 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54636158; called by mutect2, varscan2
- PLPPR4 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV64564152; called by muse, mutect2, varscan2
- PNLDC1 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV51703622, COSV51707507; called by muse, mutect2, varscan2
- PPP1R12B | c.1255-1G>T p.X419_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | catalogued as COSV61112804; called by muse, mutect2
- PPP5C | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV50139139; called by muse, mutect2, varscan2
- PRLR | c.360C>G p.D120E | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV51492857, COSV51496691; called by muse, mutect2, varscan2
- PRRC1 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56987521; called by muse, mutect2, varscan2
- PRSS1 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs1224059005, COSV61190144; called by muse, varscan2
- PSD2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs201057651; called by muse, mutect2, varscan2
- PTBP2 | c.1465A>T p.T489S (on ENST00000426398 / NM_001300986.2; = p.T481S on NM_021190.4) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV64623148; called by muse, mutect2
- PTPRH | c.3137T>A p.L1046H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54742298; called by muse, mutect2, varscan2
- PTPRN2 | c.380+2T>G p.X127_splice | Splice Site (SNP) | VAF 8/65 reads (12%) | catalogued as COSV67020503; called by muse, mutect2, varscan2
- PTPRR | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.357); catalogued as COSV51723930; called by muse, mutect2, varscan2
- RASA3 | c.1986C>G p.C662W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61863203, COSV61864398; called by muse, mutect2, varscan2
- RBM10 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV61311108; called by muse, mutect2
- RELN | c.9127C>A p.L3043M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs747144808, COSV58984231; called by muse, mutect2, varscan2
- RGS22 | c.1170G>C p.E390D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV62656914; called by muse, mutect2, varscan2
- RHOBTB2 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52569561; called by muse, mutect2, varscan2
- RIC1 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV52604540; called by muse, mutect2, varscan2
- RNF20 | c.2307G>T p.K769N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66660334; called by muse, mutect2, varscan2
- ROBO2 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165056, COSV59894479; called by muse, mutect2, varscan2
- RPL3L | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51905073; called by muse, mutect2, varscan2
- RYR1 | c.1054T>G p.S352A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV62087808; called by muse, mutect2, varscan2
- SENP2 | c.1558A>T p.R520* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV56192291; called by muse, mutect2, varscan2
- SERPINA9 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54072536; called by muse, mutect2, varscan2
- SGIP1 | c.1500A>T p.L500F | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52762254; called by muse, mutect2, varscan2
- SI | c.3766C>G p.Q1256E | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1286260158, COSV100013884, COSV100015767, COSV52264857; called by muse, mutect2, varscan2
- SIGLEC10 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774331697, COSV59478519; called by muse, mutect2, varscan2
- SIGLECL1 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV57061914; called by muse, mutect2, varscan2
- SIPA1L1 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV62168225; called by muse, mutect2, varscan2
- SIT1 | c.324C>A p.D108E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52399549; called by muse, mutect2, varscan2
- SKAP1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 22/199 reads (11%) | catalogued as rs142272724; called by muse, mutect2, varscan2
- SLC1A3 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54313836; called by muse, mutect2, varscan2
- SLC24A3 | c.1476C>A p.Y492* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60110635; called by muse, mutect2, varscan2
- SLC7A14 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV51577519, COSV51586829; called by muse, mutect2, varscan2
- SLFN11 | c.1198+1G>T p.X400_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV57697288; called by muse, mutect2, varscan2
- SMARCC1 | c.2669G>C p.R890T | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54376746; called by muse, mutect2, varscan2
- SMCHD1 | c.1341A>T p.S447= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV55251074; called by muse, mutect2, varscan2
- SPAG17 | c.4966C>T p.R1656* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as rs371789370, COSV60452343; called by muse, mutect2, varscan2
- SPINK5 | c.40del p.L14Ffs*24 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | catalogued as COSV56261156, COSV99805832; called by mutect2, pindel, varscan2
- SRRM2 | c.7733+1G>T p.X2578_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV51939709; called by muse, mutect2, varscan2
- STXBP5 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51647463; called by muse, mutect2
- STXBP5 | c.2356A>C p.I786L (on ENST00000321680 / NM_001127715.2; = p.I750L on NM_139244.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.926); catalogued as COSV51647483; called by muse, mutect2, varscan2
- SUSD1 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV62582079; called by muse, mutect2
- SYT1 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV54031521; called by muse, mutect2, varscan2
- TARS2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64694423; called by muse, mutect2, varscan2
- TENM1 | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as COSV64424333; called by muse, varscan2
- TENM3 | c.2669C>A p.P890Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV69298593, COSV69309771; called by muse, mutect2
- TFPI2 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55989790, COSV99746512; called by muse, mutect2, varscan2
- THEMIS | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs756380182, COSV64069004; called by muse, mutect2, varscan2
- TIMM50 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs200540450; called by muse, varscan2
- TKTL2 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV54917269; called by muse, mutect2, varscan2
- TLN1 | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59203718; called by muse, mutect2, varscan2
- TLX3 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99740738; called by muse, mutect2
- TMTC3 | c.2744A>T p.*915Lext*2 | Nonstop Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV57122148; called by muse, mutect2, varscan2
- TNR | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV54868322; called by muse, mutect2, varscan2
- TRAPPC12 | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60844873; called by muse, mutect2, varscan2
- TRPA1 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV51555066, COSV51570039; called by muse, mutect2, varscan2
- TRPM3 | c.1006G>T p.A336S (on ENST00000357533 / NM_001366142.2; = p.A181S on NM_020952.6) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1429313690, COSV62467143; called by muse, varscan2
- TRPS1 | c.2664G>A p.R888= (on ENST00000220888 / NM_001330599.2; = p.R901= on NM_014112.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/92 reads (18%) | catalogued as COSV55224758; called by muse, mutect2, varscan2
- TSC2 | c.1546del p.A516Qfs*19 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | catalogued as rs397515272; ClinVar: not provided; called by mutect2, pindel, varscan2
- TTN | c.98222T>C p.F32741S (on ENST00000591111; = p.F25317S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | PolyPhen probably damaging (0.961); catalogued as COSV59869790; called by muse, mutect2, varscan2
- TTN | c.9854G>T p.C3285F (on ENST00000591111; = p.C3239F on NM_003319.4) | Missense Mutation (SNP) | VAF 32/123 reads (26%) | PolyPhen possibly damaging (0.748); catalogued as COSV59869820; called by muse, mutect2, varscan2
- TTN | c.4648G>T p.V1550L (on ENST00000591111; = p.V1504L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen benign (0.013); catalogued as COSV59869871; called by muse, mutect2, varscan2
- UBE2O | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV60059573; called by muse, mutect2, varscan2
- UBE3B | c.833T>C p.L278S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55090688; called by muse, mutect2, varscan2
- UGT2B15 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV57732776; called by muse, mutect2, varscan2
- UNC5D | c.1922A>C p.Q641P | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV54766919; called by muse, mutect2, varscan2
- UPP2 | c.715T>A p.L239I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV50046260; called by muse, mutect2
- USP29 | c.1747C>A p.L583M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as COSV54139610; called by muse, mutect2, varscan2
- USP31 | c.1950G>T p.Q650H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54848952; called by muse, mutect2
- VCAM1 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54117600; called by muse, mutect2
- VGLL3 | c.921C>G p.S307R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67352340; called by muse, mutect2, varscan2
- WNT1 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV53295154; called by muse, mutect2, varscan2
- XIRP2 | c.1264G>T p.G422C (on ENST00000628543; = p.G597C on NM_152381.6) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV54680622, COSV54682372; called by muse, mutect2, varscan2
- ZFAND1 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 23/164 reads (14%) | catalogued as COSV55106502; called by muse, mutect2, varscan2
- ZFHX4 | c.7126G>C p.A2376P | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV50480035, COSV50509053, COSV51442130; called by muse, mutect2, varscan2
- ZFP41 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV58085992, COSV58086935; called by muse, mutect2, varscan2
- ZNF114 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59943482; called by muse, mutect2, varscan2
- ZNF23 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV61840437; called by muse, mutect2, varscan2
- ZNF264 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV54040517; called by muse, mutect2, varscan2
- ZNF835 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV73379142; called by muse, mutect2
- ZZZ3 | c.1686G>T p.L562F | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66231086; called by muse, mutect2, varscan2
- ADRA2A | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CMTR1 | c.1447del p.L483Wfs*3 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by pindel, varscan2
- FAF1 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- IGHV3OR16-8 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- IGKV3D-20 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IGLV1-36 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- LHX8 | c.18+1del | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | called by mutect2, pindel, varscan2
- MED23 | c.2518G>A p.G840S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); called by mutect2, varscan2
- MYH8 | c.3475del p.A1159Qfs*8 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | called by mutect2, pindel, varscan2
- NONO | c.570del p.G191Afs*25 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- OR4C16 | c.116del p.G39Vfs*4 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel
- OR5R1 | c.465del p.A156Pfs*11 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.2620_2623delinsTCCTT p.P874Sfs*138 | Frame Shift Ins (INS) | VAF 15/115 reads (13%) | called by pindel, varscan2*
- PPP2R5E | c.156del p.D53Tfs*12 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- TAF2 | c.2432_2462del p.S811Tfs*2 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel
- UGT3A1 | c.188dup p.L63Ffs*6 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- ZFP64 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- ZNF423 | c.805del p.D269Tfs*107 (on ENST00000563137 / NM_001379286.1; = p.D261Tfs*107 on NM_015069.4) | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13584A>T p.T4528= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1309384422, COSV68942920; called by muse, mutect2
- ABCC5 | c.3105G>T p.L1035= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV55586782, COSV55596668; called by muse, mutect2
- ADAM18 | c.2112C>A p.T704= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV55843337; called by muse, mutect2, varscan2
- AHSG | c.492G>C p.A164= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV56606921, COSV56607726; called by muse, mutect2, varscan2
- ATAD3C | c.1122G>C p.L374= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV58019027; called by muse, mutect2, varscan2
- BAIAP3 | c.2349G>T p.L783= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV50103499; called by muse, mutect2, varscan2
- BBS10 | c.1743G>C p.P581= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV67913016; called by muse, mutect2, varscan2
- BMP10 | c.237G>T p.V79= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV54893878; called by muse, mutect2, varscan2
- CACNG7 | c.654C>T p.R218= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55812860; called by muse, mutect2, varscan2
- CAMSAP1 | c.2706G>T p.L902= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV56718065; called by muse, mutect2, varscan2
- CDKL1 | c.774T>C p.S258= | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as COSV53577662; called by muse, mutect2, varscan2
- CHD4 | c.1275G>T p.G425= (on ENST00000357008 / NM_001363606.2; = p.G438= on NM_001273.5) | Silent (SNP) | VAF 33/274 reads (12%) | catalogued as COSV58894410; called by muse, mutect2, varscan2
- CHD6 | c.7050G>A p.E2350= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV64688084; called by muse, mutect2
- CHST4 | c.972C>A p.A324= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV58296392; called by muse, mutect2, varscan2
- CLCA4 | c.66C>A p.S22= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs753110300, COSV55365840; called by muse, mutect2, varscan2
- CNTNAP2 | c.3183C>G p.P1061= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV62141356; called by muse, mutect2, varscan2
- COL26A1 | c.516T>G p.T172= (on ENST00000313669 / NM_001278563.3; = p.T170= on NM_133457.4) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58119582; called by muse, mutect2, varscan2
- CSMD3 | c.5490C>A p.S1830= (on ENST00000297405 / NM_001363185.1; = p.S1726= on NM_052900.3) | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as COSV52093564, COSV52297977; called by muse, mutect2, varscan2
- CYP4F11 | c.1236C>A p.R412= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV56125462, COSV56130652; called by muse, mutect2, varscan2
- DDX58 | c.1204C>T p.L402= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV65881971; called by muse, mutect2, varscan2
- EPHA3 | c.1101G>T p.G367= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV60692856; called by muse, mutect2, varscan2
- FASTKD5 | c.1665A>T p.S555= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV53904023; called by muse, mutect2, varscan2
- FHL5 | c.300C>T p.S100= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58734999, COSV58735731; called by muse, mutect2, varscan2
- FLNA | c.3822C>G p.A1274= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV61036639; called by muse, mutect2, varscan2
- FMNL1 | c.2100C>A p.A700= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV58954930; called by muse, mutect2, varscan2
- FSCB | c.2040T>A p.A680= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61216378; called by muse, varscan2
- HERC1 | c.327A>T p.V109= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV71245810; called by muse, mutect2
- HIVEP2 | c.5835C>T p.S1945= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV50005337; called by muse, mutect2
- HPS5 | c.3372C>G p.L1124= (on ENST00000349215 / NM_181507.2; = p.L1010= on NM_007216.4) | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV61686989; called by muse, mutect2, varscan2
- IL1RL1 | c.1110T>A p.T370= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52111835, COSV99293582; called by muse, mutect2, varscan2
- ITCH | c.1845A>T p.A615= (on ENST00000262650 / NM_001257137.3; = p.A574= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV52929023; called by muse, mutect2
- ITGA1 | c.1962G>T p.G654= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV50876315; called by muse, mutect2, varscan2
- KIR3DL2 | c.849C>G p.G283= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- LAMA2 | c.4239C>G p.T1413= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs770520233, COSV70337364; called by muse, mutect2, varscan2
- LILRA1 | c.951G>C p.L317= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV52177505, COSV52179591; called by muse, mutect2
- MMP26 | c.348G>A p.K116= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV56171182; called by muse, mutect2, varscan2
- MON2 | c.1837C>T p.L613= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV54802542, COSV54812447; called by muse, mutect2, varscan2
- MSMO1 | c.264A>T p.P88= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV54969480; called by muse, mutect2
- MTUS2 | c.3570G>C p.L1190= (on ENST00000612955 / NM_001366650.1; = p.L169= on NM_015233.6) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs752413944, COSV60157757; called by muse, mutect2, varscan2
- MUC16 | c.15570T>C p.P5190= | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as COSV67442327; called by muse, mutect2, varscan2
- NEFH | c.2724G>A p.K908= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV60214718; called by muse, mutect2
- OR8B4 | c.495G>T p.L165= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV62069114; called by muse, mutect2, varscan2
- OR8J1 | c.786C>A p.P262= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV57316416; called by muse, mutect2
- PCDHB12 | c.1878C>A p.T626= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99506886, COSV99507591; called by mutect2, varscan2
- PCDHGB1 | c.1269G>A p.K423= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV53894110; called by muse, mutect2, varscan2
- PGLYRP4 | c.1035G>T p.L345= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV62834482; called by muse, mutect2, varscan2
- PROSER2 | c.363G>A p.E121= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53203945; called by muse, mutect2, varscan2
- PTGS1 | c.810G>T p.V270= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV56289969; called by mutect2, varscan2
- PZP | c.1785T>A p.A595= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV54353853; called by muse, mutect2
- RP1L1 | c.3462G>T p.S1154= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV66751418; called by muse, mutect2, varscan2
- RSRC2 | c.1215T>C p.A405= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100063735; called by muse, mutect2
- RXFP3 | c.241C>A p.R81= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs780429160, COSV57503789, COSV57503902; called by mutect2, varscan2
- SARAF | c.750T>C p.F250= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV56356787; called by muse, mutect2, varscan2
- SCUBE3 | c.2349A>G p.P783= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as COSV51454638; called by muse, mutect2, varscan2
- SHPRH | c.3258A>T p.I1086= (on ENST00000275233 / NM_001042683.3; = p.I1095= on NM_173082.3) | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV51604365; called by muse, mutect2, varscan2
- SIDT2 | c.1113T>A p.G371= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV54054840; called by muse, mutect2, varscan2
- SLAMF1 | c.588C>A p.L196= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV52497430; called by muse, mutect2, varscan2
- SLC14A2 | c.756C>T p.G252= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV54905847; called by muse, mutect2, varscan2
- SLC35G5 | c.276C>T p.D92= | Silent (SNP) | VAF 36/322 reads (11%) | catalogued as COSV55310242; called by muse, varscan2
- TAAR2 | c.537C>A p.V179= (on ENST00000367931 / NM_001033080.1; = p.V134= on NM_014626.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51578350; called by muse, mutect2, varscan2
- TCF23 | c.189A>T p.R63= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99940396; called by muse, mutect2
- TGIF2LX | c.24G>T p.P8= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1216899464, COSV52213098, COSV52213469; called by muse, mutect2, varscan2
- THUMPD1 | c.1014A>T p.A338= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV67262943; called by muse, mutect2, varscan2
- TMC2 | c.2130G>A p.V710= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV62649442; called by muse, mutect2, varscan2
- TMEM200A | c.642G>T p.S214= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV51648757, COSV51650140; called by muse, mutect2
- TOX2 | c.1407G>T p.G469= (on ENST00000358131 / NM_001098798.2; = p.G445= on NM_032883.3) | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV57881827; called by muse, mutect2, varscan2
- TRPS1 | c.873G>T p.L291= (on ENST00000220888 / NM_001330599.2; = p.L304= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs372146914; called by muse, mutect2, varscan2
- UBE4B | c.3579A>T p.A1193= (on ENST00000343090 / NM_001105562.3; = p.A1064= on NM_006048.5) | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV53526875; called by muse, mutect2
- UPF1 | c.2043G>C p.V681= (on ENST00000599848 / NM_001297549.2; = p.V670= on NM_002911.4) | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV53193560; called by muse, mutect2, varscan2
- VDR | c.1254G>T p.V418= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV57466710; called by muse, mutect2, varscan2
- VIT | c.699C>T p.T233= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV64894985; called by muse, mutect2, varscan2
- WDR81 | c.5796A>T p.S1932= (on ENST00000409644 / NM_001163809.2; = p.S881= on NM_152348.4) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV58478155; called by muse, mutect2, varscan2
- ZNF135 | c.1446C>A p.T482= (on ENST00000313434 / NM_001289401.2; = p.T494= on NM_003436.4) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV57879940; called by muse, mutect2, varscan2
- AL136982.4 | n.1447C>G | RNA (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- CATSPER2 | c.-1del | 5'UTR (DEL) | VAF 30/213 reads (14%) | called by mutect2, pindel, varscan2
- H3-3B | chr17:75784731 G>A | 5'Flank (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53139080; called by muse, mutect2
- H3-3B | chr17:75784733 C>A | 5'Flank (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53139089; called by muse, mutect2
- LBHD1 | c.617-531G>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100649204; called by muse, varscan2
- MIR516B1 | n.18C>T | RNA (SNP) | VAF 13/121 reads (11%) | catalogued as rs754712551; called by muse, mutect2, varscan2
- MYRF | c.46+2647C>A | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99607541; called by muse, mutect2, varscan2
- SNORD116-18 | n.78G>T | RNA (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
